Somatic mutation profile of tumor specimen MP2PRT-PASJMB-TMP1-A (aliquot MP2PRT-PASJMB-TMP1-A-1-0-D-A82L-36) from MP2PRT case MP2PRT-PASJMB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.6 years (2,780 days).
Specimen MP2PRT-PASJMB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b01439db-1e08-44e9-a63e-3abf04bc1fc2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASJMB-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASJMB-NM1-A-1-0-D-A82L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29d6940c-fabe-4dd0-91a6-156873a2e3de

The open-access MAF lists 12 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, In Frame Del 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.351A>T p.K117N | Missense Mutation (SNP) | VAF 134/407 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs770248150, COSV55504752, COSV55545304; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GTPBP10 | c.115G>A p.G39S | Missense Mutation (SNP) | VAF 147/347 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55986670, COSV55987962; called by muse, mutect2, varscan2
- KDM6A | c.3337_3338insGCATCTG p.V1113Gfs*40 | Frame Shift Ins (INS) | VAF 124/434 reads (29%) | catalogued as COSV65039079, COSV65046521, COSV99060686, COSV99060687, COSV99060690, COSV99060697; called by mutect2, pindel, varscan2
- KLF7 | c.373G>A p.V125I | Missense Mutation (SNP) | VAF 160/489 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.191); catalogued as rs536720710, COSV100519156; called by muse, mutect2, varscan2
- MYO1C | c.967G>A p.E323K (on ENST00000648651 / NM_001080779.2; = p.E288K on NM_033375.5) | Missense Mutation (SNP) | VAF 123/352 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.059); catalogued as rs766600137, COSV63000337; called by muse, mutect2, varscan2
- PCDHA10 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 128/374 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.522); catalogued as COSV104408206; called by muse, mutect2, varscan2
- CIP2A | c.2353_2355del p.E785del | In Frame Del (DEL) | VAF 40/120 reads (33%) | called by pindel, varscan2
- KLHDC8A | c.809A>T p.D270V | Missense Mutation (SNP) | VAF 161/388 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LMTK3 | c.2202C>A p.D734E | Missense Mutation (SNP) | VAF 92/212 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- NANOGP8 | c.731G>A p.G244E | Missense Mutation (SNP) | VAF 43/602 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.356); called by muse, mutect2
- PICALM | c.91A>G p.T31A | Missense Mutation (SNP) | VAF 145/468 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- AL353804.7 | chrX:73850010 T>G | 5'Flank (SNP) | VAF 14/280 reads (5%) | called by muse, mutect2
